CPTAC case C3L-05320 — Hematopoietic and reticuloendothelial systems — Myeloid Leukemias (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Myeloid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/8b277d0f-f22a-4168-a189-5df2129c4ad2

Demographics
Sex at birth: male; Race: white; Year of birth: 1990; Vital status: Alive; Country of birth: Serbia.

Diagnoses (1)
1. Acute myeloid leukemia, NOS: ICD-O-3 morphology code: 9861/3; Tissue or organ of origin: Hematopoietic system, NOS; Site of resection or biopsy: Hematopoietic system, NOS; Age at diagnosis: 29.0 years (10,606 days); Year of diagnosis: 2019; Days to last known disease status: 1,771 days (4.8 years); Progression or recurrence: no; Days to last follow up: 1,771 days (4.8 years); Calgb risk group: Favorable.
   Chemotherapy — whether it was given is not recorded by GDC; Treatment outcome: Complete Response.

Follow-up (5 entries)
- Days to follow up: 340 days; Karnofsky performance status: 100.
- Days to follow up: 711 days (1.9 years); Karnofsky performance status: 100.
- Days to follow up: 1,134 days (3.1 years); Karnofsky performance status: 100; ECOG performance status: 0.
- Days to follow up: 1,505 days (4.1 years); Karnofsky performance status: 100; ECOG performance status: 0.
- Days to follow up: 1,771 days (4.8 years); Karnofsky performance status: 100; ECOG performance status: 0.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol history: No; Alcohol intensity: Lifelong Non-Drinker.

Biospecimens (5 samples)
- Samples C3L-05320-50, C3L-05320-51, C3L-05320-52 (3 with the same recorded description): Sample type: Buccal Cell Normal; Tissue type: Normal; Specimen type: Buccal Cells; Preservation method: Frozen; Freezing method: -80 (unit not recorded by GDC).
- Samples C3L-05320-54, C3L-05320-55 (2 with the same recorded description): Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -80 (unit not recorded by GDC); Days to sample procurement: 2 days; Method of sample procurement: Blood Draw; Diagnosis pathologically confirmed: Yes.
